Somatic mutation profile of tumor specimen TCGA-25-2399-01A (aliquot TCGA-25-2399-01A-01W-0799-08) from TCGA case TCGA-25-2399, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 80.4 years (29,373 days).
Specimen TCGA-25-2399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f28a178f-7ca7-491b-a5d2-3f7a7bda9f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2399-10A (Blood Derived Normal), aliquot TCGA-25-2399-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68fb435a-dc53-4168-b6d4-c29ceed7badc

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7240C>T p.Q2414* | Nonsense Mutation (SNP) | VAF 64/151 reads (42%) | catalogued as rs863224462, COSV53752238; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 102/150 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC9 | c.4336G>T p.G1446W | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53976052; called by muse, mutect2, varscan2
- ANKLE1 | c.1257G>C p.E419D (on ENST00000394458; = p.E365D on NM_152363.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV100845746; called by muse, mutect2
- ARGFX | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100544149; called by muse, mutect2, varscan2
- ATM | c.728T>C p.L243S | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs786202096, COSV53752231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C2orf42 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 68/640 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV100033956; called by muse, varscan2
- CACNA1D | c.1479-2A>G p.X493_splice (on ENST00000350061 / NM_001128840.3; = p.X513_splice on NM_000720.4) | Splice Site (SNP) | VAF 326/720 reads (45%) | catalogued as COSV55452655; called by muse, mutect2, varscan2
- CD163L1 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58018629; called by muse, mutect2, varscan2
- CRACD | c.1652C>G p.P551R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV51724407; called by muse, mutect2, varscan2
- DUOX2 | c.4032G>T p.R1344S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66532816; called by muse, mutect2, varscan2
- ELN | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782359367, COSV52711705; called by muse, mutect2, varscan2
- EXOC7 | c.2193C>G p.F731L (on ENST00000335146 / NM_001145297.4; = p.F649L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100135414, COSV58037060, COSV58037531; called by muse, mutect2, varscan2
- EZHIP | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV57956493; called by muse, mutect2, varscan2
- FCGBP | c.10214C>T p.A3405V | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); catalogued as rs145330617; called by muse, mutect2, varscan2
- FMN2 | c.1942G>C p.A648P | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV60436161; called by muse, mutect2, varscan2
- GIGYF2 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753733236, COSV65250787; called by muse, mutect2, varscan2
- IGF2R | c.6370G>A p.A2124T | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63482272; called by muse, mutect2, varscan2
- KCNA10 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV63904834; called by muse, mutect2, varscan2
- KIR3DL1 | c.586T>G p.Y196D | Missense Mutation (SNP) | VAF 966/3031 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58492500, COSV99044393; called by muse, mutect2
- LAMA2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.021); catalogued as COSV70350622; called by muse, mutect2, varscan2
- LRRC31 | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 430/735 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52981433; called by muse, mutect2, varscan2
- LUZP2 | c.886A>C p.K296Q | Missense Mutation (SNP) | VAF 24/720 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100420280; called by muse, mutect2
- MEAK7 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs753600145, COSV59144506; called by muse, mutect2, varscan2
- MPDZ | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59945463; called by muse, mutect2, varscan2
- MUC17 | c.10540G>T p.E3514* | Nonsense Mutation (SNP) | VAF 136/409 reads (33%) | catalogued as COSV60292777; called by muse, mutect2, varscan2
- NCOR1 | c.2899A>G p.M967V | Missense Mutation (SNP) | VAF 114/163 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749822932, COSV51980910; called by muse, mutect2, varscan2
- OR11G2 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62132627; called by muse, mutect2, varscan2
- PDZD2 | c.7739T>G p.L2580R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56862203; called by muse, varscan2
- PSG7 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 470/1306 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1478971337, COSV68445476; called by muse, varscan2
- PXDN | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV53238198; called by muse, mutect2, varscan2
- RNF6 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs781210872, COSV60419371; called by muse, mutect2, varscan2
- RYR1 | c.5878G>T p.A1960S | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.152); catalogued as COSV62101249; called by muse, mutect2, varscan2
- SATB2 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 27/449 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99611464, COSV99611589; called by muse, mutect2
- SESTD1 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751171097, COSV101468143; called by muse, mutect2, varscan2
- THRAP3 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.623); catalogued as COSV63568544; called by muse, mutect2, varscan2
- TKTL2 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV99761498; called by muse, mutect2
- TTN | c.63850A>G p.I21284V (on ENST00000591111; = p.I13860V on NM_003319.4) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | PolyPhen benign (0.015); catalogued as COSV60149491; called by muse, mutect2, varscan2
- ZBP1 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334308404, COSV59062563; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1412A>T p.D471V | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV60157472; called by muse, mutect2, varscan2
- CDK15 | c.59del p.S20* | Frame Shift Del (DEL) | VAF 50/127 reads (39%) | called by mutect2, pindel, varscan2
- ABLIM3 | c.738A>T p.G246= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as COSV58644915; called by muse, mutect2, varscan2
- AKR7L | c.768C>T p.G256= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs367945519; called by muse, mutect2, varscan2
- CACNA1A | c.5439C>T p.A1813= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as rs372359926; ClinVar: likely benign; called by muse, varscan2
- DCAF17 | c.606G>T p.G202= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV100266300, COSV59830552; called by muse, mutect2
- GON4L | c.5496C>T p.I1832= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as rs753156261, COSV55189270; called by muse, mutect2, varscan2
- IQCD | c.567G>A p.E189= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as rs753072336, COSV55322085; called by muse, mutect2, varscan2
- KRT8 | c.888C>T p.H296= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs369468722; called by muse, mutect2, varscan2
- OPRL1 | c.687C>T p.L229= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs781489806, COSV61091417; called by muse, mutect2, varscan2
- PCED1B | c.1104C>T p.F368= | Silent (SNP) | VAF 134/299 reads (45%) | catalogued as rs745754589, COSV71395364; called by muse, mutect2, varscan2
- PHKB | c.1056A>G p.P352= | Silent (SNP) | VAF 77/124 reads (62%) | catalogued as COSV54525070; called by muse, mutect2, varscan2
- PRKD1 | c.879G>C p.G293= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs1391176129, COSV59574101; called by muse, mutect2, varscan2
- SEMA4A | c.603C>T p.F201= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as rs887202270, COSV100740637; called by muse, mutect2
